Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A1HV, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A1HV-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD-0-3

Melanoma, Nos 8720/3

Site: lymph node, Nos C77.9 3/12/11

Clinical History and Impression:

year old with metastatic melanoma. Tx. N1, M0, Stage III unknown primary right axillary region. Also left thyroid nodule. Now for right axillary lymph node resection and mediastinal biopsy.

Specimen(s) Received:

- 1: STATION 7 NODES
- 2: RIGHT AXILLARY LYMPHADENECTOMY

FINAL DIAGNOSIS

1) LYMPH NODES, STATION 7, EXCISION;

- MULTIPLE LYMPH NODE FRAGMENTS WITH HISTIOCYTIC INFILTRATION (CONFIRMED BY CD68 IMMUNOSTAINING) AND GRANULOMAS
- STAINS FOR CARCINOMA (AE1/AE3) AND MELANOMA (S-100 AND MELAN A) ARE NEGATIVE FOR MALIGNANCY

2) LYMPH NODES, RIGHT AXILLA, DISSECTION:

- ONE OF FIFTEEN LYMPH NODES POSITIVE FOR METASTATIC MELANOMA (1/15) [TUMOR CELLS STAIN POSITIVELY FOR S-100 PROTEIN AND ARE NEGATIVE FOR CYTOKERATIN]

Pathologist:

, Ph.D.

* Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

M.D.:

M.D.)

1) Received fresh, labeled with the patient's name, medical record number and "station 7 nodes", are multiple brown-red rubbery lymph nodes measuring 2.3 x 2.2 x 0.3 cm in aggregate. The entire specimen is submitted into two cassettes.

2) Received fresh, labeled with the patient's name, medical record number and "right axillary lymphadenectomy", consists of a piece of tan-pink fibrofatty tissue measuring 11 cm x 7 cm x 3.5 cm. There are several tan-red rubbery lymph nodes ranging from 0.3 cm to 1.5 x 1.2 cm. These lymph nodes are all entirely submitted. There is also a large group of matted lymph nodes measuring 6 cm x 3.6 cm x 2.7 cm. A cut section of the matted lymph nodes reveals pink-tan rubbery soft tissue in which a representative section is submitted in cassette #1. The remainder of lymph nodes are submitted as

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

follows: Cassettes #2-4 = contain bisected lymph nodes, cassettes #5-8 = contain multiple possible lymph nodes.

Summary of Stains Performed and Reviewed	Count
Keratin, AE1/AE3 PK *	2
Macrophage, CD68 *	1
Melan-A *	1
S-100 Protein *	2

*The immunohistochemical profile may include the use of Analyte Specific Reagents, or Research Agents, whose performance characteristics have not been established by the supplier. The histochemical tests were developed and their performance characteristics were determined by the laboratory. It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary for this test. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. External and internal controls stained appropriately.

Summary of Tissue Submitted for Microscopic Examination		Block Detail	
	# Blocks	Designation	# Description
Part 1) STATION 7 NODES	2	LN	(2) (No Description)
Part 2) RIGHT AXILLARY LYMPHADENECTOMY	8	BLN	(3) (No Description)
		LN	(3) (No Description)
		LN	(1) MULTIPLE LN'S
		LN	(1) REP SECTION
Total:		10	

END OF REPORT

Source: NCI Genomic Data Commons file 36c5f761-338d-46ca-bb2f-b9be5689de09 (TCGA-DA-A1HV.4FC1592D-0BF9-4658-A498-E4F18C2EFE08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).